Somatic mutation profile of tumor specimen BA2538D (aliquot aq-BA2538D) from BEATAML1.0 case 2283, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 81.0 years (29,603 days).
Specimen BA2538D: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f95fb283-756f-4a93-a993-9c15550c9b05.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2749D (Solid Tissue Normal), aliquot aq-BA2749D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3cdb711a-f577-4f14-b521-c72247fc031e

The open-access MAF lists 16 somatic variants for this specimen: 12 protein-altering or splice-affecting, 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Intron 2, Silent 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IGFN1 | c.799C>T p.R267C | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs997530914, COSV55169239; called by mutect2, varscan2
- PKD1 | c.10951G>T p.G3651C (on ENST00000262304 / NM_001009944.3; = p.G3650C on NM_000296.4) | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM057347; called by muse, mutect2
- SOX17 | c.247C>A p.R83S | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV52026676; called by muse, mutect2
- ADRB1 | c.612C>A p.D204E | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT tolerated (0.59); PolyPhen benign (0.005); called by muse, mutect2
- ATP6AP2 | c.35C>A p.A12E | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.041); called by muse, mutect2
- C2CD4B | c.964G>A p.D322N | Missense Mutation (SNP) | VAF 45/101 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- HARBI1 | c.46G>T p.G16C | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.956); called by muse, mutect2
- HEATR1 | c.2072G>T p.G691V | Missense Mutation (SNP) | VAF 6/121 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0.001); called by muse, mutect2
- PDILT | c.412G>A p.V138M | Missense Mutation (SNP) | VAF 45/101 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.123); called by muse, varscan2
- WDFY2 | c.311T>C p.M104T | Missense Mutation (SNP) | VAF 62/139 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.023); called by muse, varscan2
- ZBTB8A | c.1223C>A p.S408Y | Missense Mutation (SNP) | VAF 87/205 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- ZNF484 | c.794A>T p.H265L | Missense Mutation (SNP) | VAF 11/126 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.079); called by muse, mutect2
- LILRB3 | c.1314T>G p.G438= | Silent (SNP) | VAF 12/115 reads (10%) | catalogued as rs770310553; called by muse, mutect2
- CT83 | c.-11G>T | 5'UTR (SNP) | VAF 4/50 reads (8%) | catalogued as rs200634429, COSV100902502, COSV100902514; called by muse, mutect2
- DENND3 | c.956+2300C>A | Intron (SNP) | VAF 4/52 reads (8%) | called by muse, mutect2
- MARS1 | c.2463+57A>G | Intron (SNP) | VAF 98/228 reads (43%) | called by mutect2, varscan2
